Somatic mutation profile of tumor specimen 0DQMPS from CCDI case PBCFCV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (559 days).
Specimen 0DQMPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69569f6e-080a-4c03-9285-4e045c6c10e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQMQX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dde5601-190e-452a-8547-fc9494126997

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK11 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 64/654 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.089); catalogued as rs759076573, COSV52242394; called by muse, mutect2
- PCLO | c.3053T>A p.V1018E | Missense Mutation (SNP) | VAF 65/1214 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100430436; called by muse, mutect2
- ASTN1 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 149/478 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- RASAL1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 187/621 reads (30%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 115/856 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
